Somatic mutation profile of tumor specimen 0DQ55M from CCDI case PBCEKM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Mandible; Age at diagnosis: 2.7 years (996 days).
Specimen 0DQ55M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69a8d616-1bb1-4f28-b474-4257f6ad3a59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ55U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e802ef3-1738-4d8a-bf5e-0951bdaf6e02

The open-access MAF lists 30 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 9, Intron 4, Splice Site 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 72/652 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs1180689242, COSV62563242; called by muse, mutect2, varscan2
- B4GALNT4 | c.2435G>A p.R812Q | Missense Mutation (SNP) | VAF 179/372 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.067); catalogued as rs1383962298, COSV100327965; called by muse, mutect2, varscan2
- BDKRB1 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 30/558 reads (5%) | catalogued as COSV53705912; called by muse, mutect2
- DMRT3 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 99/220 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs773043267; called by muse, mutect2, varscan2
- GPC2 | c.325+1G>A p.X109_splice | Splice Site (SNP) | VAF 30/356 reads (8%) | catalogued as rs773483944; called by muse, mutect2
- MGST3 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 73/410 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs538652119; called by muse, mutect2, varscan2
- NKIRAS2 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as rs1555653642; called by muse, mutect2, varscan2
- VWA1 | c.667A>T p.I223F | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs759035997; called by muse, mutect2, varscan2
- C18orf21 | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 88/742 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GUCY2C | c.2657G>C p.G886A | Missense Mutation (SNP) | VAF 28/970 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MICAL2 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 157/412 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MUC12 | c.1410T>G p.S470R (on ENST00000379442; = p.S327R on NM_001164462.1) | Missense Mutation (SNP) | VAF 71/451 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- PTPRM | c.1009A>G p.S337G | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RAD9B | c.911dup p.A305Gfs*25 | Frame Shift Ins (INS) | VAF 100/339 reads (29%) | called by mutect2, varscan2
- SKOR2 | c.909C>A p.H303Q | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- TREML2 | c.884C>A p.A295E | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, varscan2
- TUBA1C | c.1139A>G p.N380S | Missense Mutation (SNP) | VAF 70/628 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ABCC11 | c.462G>A p.V154= | Silent (SNP) | VAF 109/418 reads (26%) | catalogued as rs1225084562; called by muse, mutect2, varscan2
- ALS2 | c.1026C>T p.T342= | Silent (SNP) | VAF 30/705 reads (4%) | catalogued as rs911504819; called by muse, mutect2
- ATAD1 | c.429C>G p.A143= | Silent (SNP) | VAF 18/650 reads (3%) | called by muse, mutect2
- CHST1 | c.429G>A p.P143= | Silent (SNP) | VAF 150/334 reads (45%) | catalogued as rs771836041, COSV57325680; called by muse, mutect2, varscan2
- MYO9B | c.5133G>A p.S1711= | Silent (SNP) | VAF 59/482 reads (12%) | catalogued as rs774531645; called by muse, mutect2, varscan2
- NFRKB | c.2937A>G p.T979= (on ENST00000446488 / NM_001143835.2; = p.T1004= on NM_006165.3) | Silent (SNP) | VAF 50/225 reads (22%) | catalogued as rs1430112678, COSV58756119; called by muse, mutect2, varscan2
- SPTAN1 | c.4971C>T p.A1657= | Silent (SNP) | VAF 32/586 reads (5%) | catalogued as COSV100823234; called by muse, mutect2
- TBC1D32 | c.3357C>T p.G1119= | Silent (SNP) | VAF 112/480 reads (23%) | called by muse, mutect2, varscan2
- XIRP1 | c.3525C>A p.V1175= | Silent (SNP) | VAF 126/400 reads (32%) | called by muse, mutect2, varscan2
- EML5 | c.4005-73G>T | Intron (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2
- GPC2 | c.892+77C>T | Intron (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- MYCBP2 | c.8027-87A>G | Intron (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2, varscan2
- TFPI2 | c.271+20C>A | Intron (SNP) | VAF 164/593 reads (28%) | called by muse, mutect2, varscan2
